Surgical pathology report (de-identified scan), TCGA case TCGA-2F-A9KQ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Erasmus MC, specimen TCGA-2F-A9KQ-01A (Primary Tumor).

Pathology report

Date of tumor procurement

Date of report

Histologic diagnosis

High grade muscle invasive urothelial cell carcinoma covering most of the bladder wall. T3aG3 N0 M0

Anatomic site and laterality

Bladder wall NOS

Tumor size

5.5cm diameter

Lymph node status

A total of 18 lymph nodes all without tumor localization.

ICD-0.3

Carcinoma, urothelial
8120/3

Site Bladder NOS
C67.9

qW 1/29/14

Source: NCI Genomic Data Commons file 46a2b301-8ece-4b11-9131-4e650a30ff10 (TCGA-2F-A9KQ.F35113C2-F4CC-43EC-8C52-B71B357DDA46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).